Gene-level copy-number profile of tumor specimen TCGA-ER-A193-06A from TCGA case TCGA-ER-A193, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.2 years (22,702 days).
Specimen TCGA-ER-A193-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.28a7d729-7555-4545-924b-3dec49b54230.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A193-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0b38623-3884-44e1-ba3b-8ea7c669b95d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 12,578; copy number 2: 43,695; copy number 3: 2,392; copy number 4: 980; copy number 5: 15; copy number 6: 58; copy number 7: 5; copy number 33: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A193-06A-12D-A191-01): tumor purity 0.67, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,367,424–23,898,054, 46 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 126 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:4,299,390–5,629,748, 44 genes, copy number 6 (within-gene range 1–6): AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1.
- chr12:67,131,567–68,971,570, 48 genes, copy number 33: RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:95,551,582–97,276,209, 34 genes, copy number 5–7 (within-gene range 1–7): PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409.

Autosomal genes at a single copy (total copy number 1): 10,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
